Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9EA, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9EA-01A (Primary Tumor).

Date of surgery :

Left eye enucleation

Macroscopy

The enucleation specimen contains a fragment of optic nerve of 12 mm. There is no visible extrascleral extension. Samples have been made for cryo preservation and for xenografts .The specimen has been then included entirely.

Microscopy

Analysis of the specimen shows an intraocular tumor which morphological characteristics are those of a melanoma. The lesion is composed of fusiform cells. The pigment content is moderate. The mitotic index is low (less mitosis by field at the 40 magnification.) There are no necrosis. The lesion is implanted at the posterior pole, covering the emergence of the optic nerve. It measures 13 mm at the basis with 7 mm of thickness. It stays distant from the ciliary processes. At the posterior pole, the optic foramen, the optic nerve and the meningeal sheaths are free. The cut end of the optic nerve is also free.

Conclusion

Choroidal melanoma with fusiform cells

Size of the tumor: 10 mm

Neither involvement of the sclera nor extrascleral extension

Ciliary processes, optic foramen and optic nerve are free.

Diffuse	lw 12/30/13	Yes	No
Discrepancy			
Metastatic Discrepancy			
Local Discrepancy			
Local Discrepancy History			
Qualification Primary Tumor			

Source: NCI Genomic Data Commons file 60262ab2-5fd1-4e15-9678-bfcfbed2696a (TCGA-V4-A9EA.98EC98E0-F65F-40F7-A499-E9F6C8DF6C02.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).